Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7J3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7J3-01A (Primary Tumor).

ICD-O-3

Oligodendroglioma,
grade III 9451/3

Site Brain, supratentorial NOS
71.0
9/30/13

glioma with oligodendroglial differentiation
Anaplasia is diagnosed for focal high proliferation and
vascular endothelial proliferation. IDH1 R132H mutation present
p16 loss present.

Diagnosis: Anaplastic oligodendroglioma WHO grade III

untranslated original report
is housed at the BCR

Source: NCI Genomic Data Commons file 1f037e3e-9903-48b1-a524-8b1d5b255b5c (TCGA-S9-A7J3.EC6B158C-2D75-43CF-8D80-7FF9DEBCB199.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).